Gene-level copy-number profile of tumor specimen ALCH-B4QD-TTP1-A from ALCHEMIST case ALCH-B4QD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.1 years (28,531 days).
Specimen ALCH-B4QD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f7d60b8-1a09-460b-927c-d77bb25ee0d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4QD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/75e7828d-823c-4eb1-b426-5d02e6ff50ec

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 32; copy number 4: 32,074; copy number 5: 2,493; copy number 6: 12,234; copy number 7: 2,687; copy number 8: 8,711; copy number 9: 81; copy number 10: 84; copy number 12: 1; copy number 44: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 158 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,006,623, 38 genes, copy number 9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2.
- chr5:146,110,566–146,339,251, 6 genes, copy number 10 (within-gene range 8–10): LARS1, RPL35AP16, RPL35AP17, AC091959.1, RBM27, RNU7-180P.
- chr6:170,639,606–170,737,777, 3 genes, copy number 9–44: OR4F7P, WBP1LP8, AL731684.1.
- chr7:77,461,458–77,798,434, 5 genes, copy number 9: GCNT1P5, PTPN12, APTR, RSBN1L, TMEM60.
- chr7:104,894,628–105,567,677, 17 genes, copy number 9 (within-gene range 8–9): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1.
- chr14:18,333,726–19,700,650, 68 genes, copy number 10 (broad region; genes not listed).
- chr14:20,684,177–20,784,293, 10 genes, copy number 10: ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2.
- chr14:44,924,324–45,253,540, 10 genes, copy number 9: KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1.
- chr21:12,999,676–13,016,692, 1 gene, copy number 12: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
